Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5874, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5874-01A (Primary Tumor).

[page 1 of 5]
Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

=====

CLINICAL HISTORY

[REDACTED]

on

imaging has a left frontal, 4 cm slightly enhancing tumor.

OPERATIVE DIAGNOSES

Left frontal brain lesion

Operation/Specimen:

A: Left frontal brain tumor, biopsy

B: Left frontal brain tumor, biopsy

C: Left frontal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A, B, and C. Brain, left frontal, excisional biopsies:

1. Oligodendroglioma, with atypical features.

MIB-1 proliferation index: 18%.

See Microscopy Description and Comment.

COMMENT

The specimens contain portions of cerebrum that are lightly to heavily infiltrated by a neoplastic proliferation of glial cells that have an oligodendroglial phenotype. There is only slight nuclear pleomorphism, rarely

one mitotic figure, but a high MIB-1 proliferation index of about 18% in focal

more cellular areas. There is occasionally endothelial hyperplasia, but no

microvascular cellular proliferation. There is not necrosis.

The neoplasm is an oligodendroglioma with low histological grade features.

However, the focal endothelial hyperplasia and elevated proliferation index

may portend enhanced biological activity.

The pathological findings may be correlated with clinical, imaging, and

operative findings for their final interpretation and patient's follow up.

[page 2 of 5]
Electronically Signed Out

=====

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial

dilution of methylated positive control DNA into unmethylated DNA, and was

assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or

extensive tissue necrosis, may preclude the detection of methylated MGMT

promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by [REDACTED]. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

[REDACTED]

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

[page 3 of 5]
POSITIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is detected.

Informative loci are: D1S1592, D1S552, D19S219, D19S412

Results-Comments

Test performed on DNA extracted from tumor tissue paraffin block and DNA from peripheral blood for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p

and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by [REDACTED]. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

Electronically Signed Out

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A.

Left frontal brain tumor, biopsy: Infiltrating glioma. [REDACTED]

[REDACTED] results

reported to

the Physician of Record.

[page 4 of 5]
B.

Left frontal brain tumor, biopsy: Infiltrating glioma, one abnormal vessel.

Touch preparation smears performed at [REDACTED] and results

reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A.

"Left frontal tumor," received fresh, three fragments, 0.6 cm in aggregate.

Soft, tannish-white. In total, A1.

B.

"Left frontal tumor," received fresh, one fragment, 0.5 cm. Semi firm, white.

In total, B1.

C.

Left frontal tumor, received are multiple fragments 1.5 x 1.0 x 0.9 cm in

aggregate. Soft, pink-tan to gray-white. In total, C1-2

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates a paucifibrillary positive background. The NeuN depicts the infiltration of the cerebral cortex and

white matter by the neoplastic proliferation. The CD34 demonstrates a capillary-type microvascular network, with some endothelial hyperplasia, but

without microvascular cellular proliferation. The CD163 highlights prominent

microglia, however almost exclusively perivascular. With the MIB-1 there is a

proliferation index of about 18% in focal more cellular/active areas.

ICD-9(s):

237.5 237.5

Histo Data

Part A: Left frontal brain tumor, biopsy

Stain/cnt

H/E x 1

TPS H/E x 1

Block

1

1

Ordered

Comment

Part B: Left frontal brain tumor, biopsy

Stain/cnt

H/E x 1

Block

1

Ordered

Comment

[page 5 of 5]
TPS H/E x 1

1

Part C: Left frontal tumor, excision biopsy

Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
CD163 Vector x 1	2		
CD34-DA x 1	2		
mGFAP-DA x 1	2	0	
H/E x 1	2		
LOH-slides x 1	2		
MGMT-curls x 1	2		
MIB1-DA x 1	2		
NeuN x 1	2		
P53DO7 x 1	2		
H/E x 1	3		

*** End of Report ***

Source: NCI Genomic Data Commons file 8582b969-3ca7-4ad6-acb9-b9e966f12a63 (TCGA-DU-5874.EDD1C152-5B40-4F2F-A7BC-454F1837142A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).